Somatic mutation profile of tumor specimen TCGA-02-2486-01A (aliquot TCGA-02-2486-01A-01D-1494-08) from TCGA case TCGA-02-2486, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.0 years (23,394 days).
Specimen TCGA-02-2486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6fdd908-5766-405d-a125-7cbf2eae47fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2486-10A (Blood Derived Normal), aliquot TCGA-02-2486-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523e6728-6954-4f10-9ca3-2beb93a00eaa

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs772388824, COSV63659909; called by muse, mutect2, varscan2
- ALKAL1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145116532; called by muse, mutect2, varscan2
- ASXL3 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs764709254, COSV52462510; called by muse, mutect2, varscan2
- CAD | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 156/640 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53026282; called by muse, varscan2
- CCDC105 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as rs762392320, COSV52963816; called by muse, mutect2, varscan2
- CERS3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752230253, COSV52567747; called by muse, mutect2, varscan2
- CPA2 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV55979412; called by muse, mutect2, varscan2
- CSMD3 | c.400A>T p.R134W | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52165118; called by muse, mutect2
- DEAF1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.51); catalogued as rs371722695; called by muse, mutect2, varscan2
- ELAPOR2 | c.2912A>T p.E971V (on ENST00000450689 / NM_001142749.3; = p.E804V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51886262; called by muse, mutect2, varscan2
- GABRA6 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV50877577, COSV50900675; called by muse, mutect2, varscan2
- GABRB2 | c.1474C>T p.R492C (on ENST00000274547; = p.R454C on NM_000813.3) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50909148; called by muse, mutect2, varscan2
- GABRP | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145233692, COSV54665748; called by muse, mutect2, varscan2
- GPR52 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 138/414 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs746603649, COSV52291614; called by muse, mutect2, varscan2
- HECW1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs779527048, COSV67825450; called by muse, mutect2, varscan2
- HNRNPCL1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs4026148, COSV58610262; called by muse, mutect2, varscan2
- HNRNPCL1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1370547609, COSV100509148, COSV58611111; called by muse, mutect2, varscan2
- HRH2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372317500; called by muse, mutect2, varscan2
- HSPG2 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as rs1332584154, COSV65930008; called by muse, mutect2, varscan2
- IL31RA | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 78/193 reads (40%) | catalogued as rs760422651, COSV51681441; called by muse, mutect2, varscan2
- ISM1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs776466599, COSV52604368; called by muse, mutect2, varscan2
- KCNQ5 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781763407, COSV59658177; called by muse, mutect2, varscan2
- KDM2B | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs782132082, COSV65640263; called by muse, mutect2, varscan2
- KIF21B | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378904806, COSV59756795; called by muse, mutect2, varscan2
- LCT | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as rs565990613, COSV51552443, COSV51553501; called by muse, mutect2, varscan2
- LRP2 | c.7729C>T p.R2577C | Missense Mutation (SNP) | VAF 148/400 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367997832, COSV55550899; called by muse, mutect2, varscan2
- MPP3 | c.1345A>C p.N449H | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.461); catalogued as COSV68198070; called by muse, mutect2, varscan2
- MYH13 | c.5108G>A p.R1703H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142532419; called by muse, mutect2, varscan2
- NME8 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs751830410, COSV52246254; called by muse, mutect2, varscan2
- NPY5R | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs375176738, COSV58451934; called by muse, mutect2, varscan2
- NSUN7 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 44/155 reads (28%) | catalogued as COSV57273580; called by muse, mutect2, varscan2
- OR2T4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 146/432 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs141022739; called by muse, mutect2, varscan2
- OR4C12 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV58859833; called by muse, mutect2, varscan2
- OR51E1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759603811, COSV67809620; called by muse, mutect2, varscan2
- OR6C65 | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101110170, COSV101110211; called by muse, mutect2, varscan2
- OR8D4 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 181/528 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV58430083; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2180G>A p.R727Q (on ENST00000259318 / NM_001136562.3; = p.R958Q on NM_007203.5) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs139808664; called by muse, mutect2, varscan2
- PAN3 | c.1772A>C p.Y591S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1380447543, COSV56702825; called by muse, mutect2, varscan2
- PPP1R26 | c.1253C>A p.T418N | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV63355411; called by muse, mutect2, varscan2
- RHOQ | c.288T>A p.F96L | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV53189935; called by muse, mutect2, varscan2
- RXFP2 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1043084858, COSV53634652; called by muse, mutect2, varscan2
- SGK1 | c.1038del p.F346Lfs*12 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as COSV99398206; called by mutect2, pindel, varscan2
- SLC2A1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs794727642, CM077636, CM101701, COSV65286784; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SSC4D | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs770061203, COSV51882151; called by muse, mutect2, varscan2
- STK31 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199698256; called by muse, mutect2
- TMEM161A | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs761544241, COSV50776566; called by muse, mutect2, varscan2
- CDKN2C | c.175dup p.R59Kfs*4 | Frame Shift Ins (INS) | VAF 72/169 reads (43%) | called by mutect2, pindel, varscan2
- IGHV3-21 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- KCNMB4 | c.337-2del p.X113_splice | Splice Site (DEL) | VAF 61/217 reads (28%) | called by mutect2, pindel, varscan2
- ACKR2 | c.822G>A p.T274= | Silent (SNP) | VAF 136/272 reads (50%) | catalogued as rs1056643270, COSV56177708; called by muse, mutect2, varscan2
- ANKS1B | c.969C>T p.T323= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs758739073, COSV61348502; called by muse, mutect2, varscan2
- ARFGEF3 | c.3090C>T p.S1030= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs373777982; called by muse, mutect2, varscan2
- BEND3 | c.564C>T p.N188= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs782123009, COSV64680961; called by muse, mutect2, varscan2
- GFRA2 | c.687C>T p.C229= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs778196839, COSV60778844; called by muse, mutect2, varscan2
- GRPR | c.111G>A p.P37= | Silent (SNP) | VAF 191/282 reads (68%) | catalogued as rs1246365674, COSV66669232; called by muse, mutect2, varscan2
- MAN2B2 | c.2922C>T p.G974= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- NUP62 | c.1131C>T p.R377= | Silent (SNP) | VAF 97/269 reads (36%) | catalogued as rs1450352055, COSV61311943; called by muse, mutect2, varscan2
- OR2AG1 | c.765C>G p.A255= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV56625944; called by muse, mutect2, varscan2
- PLXNB1 | c.1506C>T p.C502= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs1198423612, COSV56486542; called by muse, mutect2, varscan2
- PRDM13 | c.1539G>A p.G513= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV65029561; called by muse, mutect2, varscan2
- SLCO3A1 | c.1089A>C p.A363= | Silent (SNP) | VAF 158/468 reads (34%) | catalogued as COSV59229160; called by muse, mutect2, varscan2
- STAT5A | c.1536C>T p.N512= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV61806604; called by muse, mutect2, varscan2
